Somatic mutation profile of tumor specimen TCGA-BP-4986-01A (aliquot TCGA-BP-4986-01A-01D-1462-08) from TCGA case TCGA-BP-4986, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 75.6 years (27,612 days).
Specimen TCGA-BP-4986-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 40d23444-25d0-4757-8475-e24c60b0e271.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4986-11A (Solid Tissue Normal), aliquot TCGA-BP-4986-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8397e0bf-81e4-44b7-810a-164b3cc1ba2d

The open-access MAF lists 42 somatic variants for this specimen: 33 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 26, Silent 9, Frame Shift Del 3, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD3A | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs771376142, COSV59232479; called by muse, mutect2, varscan2
- ATP4A | c.2071G>C p.E691Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.924); catalogued as COSV52871425, COSV52872555; called by muse, mutect2
- BRD2 | c.424A>G p.M142V | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.161); catalogued as COSV66374762; called by muse, mutect2, varscan2
- CAD | c.3733G>A p.E1245K | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.446); catalogued as COSV53032854; called by muse, mutect2, varscan2
- CEP162 | c.1618A>G p.K540E | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV57625761; called by muse, mutect2, varscan2
- DEGS1 | c.571G>A p.V191M | Missense Mutation (SNP) | VAF 112/513 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.16); catalogued as rs188450448; called by muse, mutect2, varscan2
- EPHA5 | c.2648C>G p.T883S | Missense Mutation (SNP) | VAF 62/264 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56679439; called by muse, mutect2, varscan2
- EPS15L1 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs370990400; called by muse, mutect2, varscan2
- GTPBP6 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 9/101 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs188588834, COSV58205075; called by muse, mutect2, varscan2
- HIF1A | c.2260del p.R754Vfs*2 | Frame Shift Del (DEL) | VAF 19/163 reads (12%) | catalogued as COSV60189211, COSV60191098; called by mutect2, varscan2
- MGA | c.5027C>G p.P1676R | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.221); catalogued as COSV54963162, COSV54964661, COSV99581021; called by muse, mutect2, varscan2
- MYO1E | c.1144T>C p.Y382H | Missense Mutation (SNP) | VAF 95/393 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.928); catalogued as COSV55697279; called by muse, mutect2, varscan2
- NCF2 | c.1075A>T p.K359* | Nonsense Mutation (SNP) | VAF 74/302 reads (25%) | catalogued as COSV62316997; called by muse, varscan2
- NKAPL | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs760414569, COSV59199651; called by muse, mutect2, varscan2
- OR2T10 | c.185T>G p.F62C | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.369); catalogued as COSV57898659; called by muse, mutect2, varscan2
- PAIP1 | c.403T>A p.F135I | Missense Mutation (SNP) | VAF 99/481 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59088147; called by muse, mutect2, varscan2
- PIGC | c.214T>A p.W72R | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV51131298; called by muse, mutect2, varscan2
- PLEC | c.1825C>T p.R609C (on ENST00000322810 / NM_201380.4; = p.R499C on NM_000445.5) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs559590378, COSV59692175; called by muse, mutect2, varscan2
- PNPLA8 | c.844T>G p.S282A | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.138); catalogued as COSV57555304; called by muse, mutect2, varscan2
- POLD1 | c.795G>A p.W265* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as COSV101486806, COSV70958001; called by muse, mutect2, varscan2
- PRKCE | c.20T>A p.L7H | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.326); catalogued as COSV60331744; called by muse, mutect2, varscan2
- RYR1 | c.6331G>A p.V2111M | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as rs773607432, COSV62099033; called by muse, mutect2, varscan2
- RYR1 | c.9905C>A p.P3302Q | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs777896104, COSV100615401, COSV62092248, COSV62103390; called by muse, varscan2
- SLIT2 | c.144C>G p.S48R | Missense Mutation (SNP) | VAF 10/167 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.313); catalogued as COSV56599221; called by muse, mutect2
- TBC1D16 | c.796G>C p.D266H | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.804); catalogued as COSV60477016, COSV60482027; called by muse, mutect2, varscan2
- VHL | c.408dup p.V137Cfs*7 | Frame Shift Ins (INS) | VAF 62/293 reads (21%) | catalogued as COSV56544783, COSV56547644; called by pindel, varscan2*
- VPS54 | c.1554A>G p.I518M | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as rs1341570958, COSV55446249; called by muse, mutect2, varscan2
- ZNF234 | c.456G>C p.E152D | Missense Mutation (SNP) | VAF 12/147 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV70604372; called by muse, mutect2
- ZNF473 | c.2232G>C p.E744D | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as COSV54525538; called by muse, mutect2, varscan2
- CALU | c.832G>T p.D278Y | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHUK | c.1531del p.W511Gfs*46 | Frame Shift Del (DEL) | VAF 40/174 reads (23%) | called by mutect2, pindel, varscan2
- NF2 | c.240+1_240+2del p.X80_splice | Splice Site (DEL) | VAF 31/94 reads (33%) | called by mutect2, pindel, varscan2
- NGRN | c.860_863del p.F287Cfs*35 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | called by pindel, varscan2
- ENAM | c.3096C>A p.G1032= | Silent (SNP) | VAF 43/151 reads (28%) | catalogued as COSV68537289; called by muse, mutect2, varscan2
- F11 | c.1626C>T p.N542= | Silent (SNP) | VAF 36/115 reads (31%) | catalogued as rs750622854, COSV53001256; called by muse, mutect2, varscan2
- FREM2 | c.8571T>C p.F2857= | Silent (SNP) | VAF 60/270 reads (22%) | catalogued as COSV54855425; called by muse, varscan2
- GPRC6A | c.2691T>C p.D897= | Silent (SNP) | VAF 22/286 reads (8%) | catalogued as COSV59956494; called by muse, mutect2
- IL2RA | c.808A>C p.R270= | Silent (SNP) | VAF 42/176 reads (24%) | catalogued as COSV56923604; called by muse, mutect2, varscan2
- KLHDC7A | c.393G>A p.S131= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs781393477, COSV101272759, COSV68771270; called by muse, mutect2, varscan2
- NGRN | c.870A>G p.R290= | Silent (SNP) | VAF 30/120 reads (25%) | catalogued as COSV58961928; called by muse, varscan2
- PCDHA9 | c.1998G>A p.L666= | Silent (SNP) | VAF 53/119 reads (45%) | catalogued as COSV65333967; called by muse, mutect2, varscan2
- TTN | c.768G>A p.R256= | Silent (SNP) | VAF 50/157 reads (32%) | catalogued as rs886043078, COSV60403775; ClinVar: uncertain significance; called by muse, mutect2, varscan2
